Surgical pathology report (de-identified scan), TCGA case TCGA-34-5239, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-34-5239-01A (Primary Tumor).

FINAL DIAGNOSIS:

Summary Statement

The left upper lobe neoplasm is an invasive moderately differentiated squamous cell carcinoma measuring 3.5 cm. A microscopic satellite focus of squamous cell carcinoma (0.1 cm) is identified in the same lobe. All margins of resection are free of tumor. Visceral pleural invasion is identified. All lymph nodes sampled show no evidence of metastatic carcinoma. The stage is T4 N0 MX (due to the presence of a microscopic satellite focus). ✓

PART 1: LYMPH NODE, LEVEL 11 NEAR LINGULAR ARTERY, BIOPSY –
ONE REACTIVE LYMPH NODE. NO CARCINOMA SEEN.

PART 2: LYMPH NODE, LEVEL 11 NEAR POSTERIOR UPPER LOBE ARTERY, BIOPSY –
ONE REACTIVE LYMPH NODE FRAGMENT. NO CARCINOMA SEEN.

PART 3: LYMPH NODE, LEVEL 11 NEAR UPPER DIVISION BRONCHUS, BIOPSY –
FRAGMENTS OF ONE LYMPH NODE. NO CARCINOMA SEEN.

PART 4: LYMPH NODE, LEVEL 11 NEAR AORTO-APICAL TRUNK, BIOPSY –
FRAGMENTS OF ONE LYMPH NODE. NO CARCINOMA SEEN.

PART 5: LUNG, LEFT UPPER LOBE, LOBECTOMY –

- A. INVASIVE MODERATELY DIFFERENTIATED SQUAMOUS CELL CARCINOMA (3.5 CM), WITH EXTENSIVE NECROSIS (APPROXIMATELY 60%).
- B. MICROSCOPIC SATELLITE FOCUS (0.1 CM) OF SQUAMOUS CELL CARCINOMA.
- C. ANGIOLYMPHATIC INVASION IDENTIFIED.
- D. VISCERAL PLEURAL INVASION IDENTIFIED.
- E. MARGINS OF RESECTION FREE OF TUMOR.
- F. SEVEN REACTIVE LYMPH NODES WITH ANTHRACOSILICOTIC NODULES. NO CARCINOMA SEEN.
- G. STAGE T4 N0 MX.
- H. BACKGROUND LUNG SHOWING EMPHYSEMA, AIRSPACE SMOKER'S MACROPHAGES, DUST MACULES, AND DUST-LADEN MACROPHAGES.

PART 6: LYMPH NODE, LEVEL 5, BIOPSY –
TWO REACTIVE LYMPH NODES WITH ANTHRACOSILICOTIC NODULES. NO CARCINOMA SEEN. ✓

PART 7: LYMPH NODE, LEVEL 9, BIOPSY –
ONE REACTIVE LYMPH NODE. NO CARCINOMA SEEN. ✓

PART 8: LYMPH NODE, LEVEL 7, BIOPSY –
ONE REACTIVE LYMPH NODE. NO CARCINOMA SEEN. FRAGMENTS OF SKELETAL MUSCLE ALSO PRESENT.

Addendum

The VVG stains show visceral pleural invasion by the carcinoma. The PAS and PAS/D stains show rare positivity in the neoplastic cells (less than 1%). The mucicarmine stain is negative. The diagnosis is unchanged.

Source: NCI Genomic Data Commons file 977f54f4-9000-4d71-ab04-d290f589f965 (TCGA-34-5239.63C38B6B-14D2-4A12-BD73-957AC5207FEE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).